Surgical pathology report (de-identified scan), TCGA case TCGA-5P-A9KF, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site University Hospital Erlangen, specimen TCGA-5P-A9KF-01A (Primary Tumor).

ICD-O-3
Carcinoma, papillary renal cell 8260/3
Site: (L) Kidney NOS C64.9
5/6/14

Slide of nephrectomy with two focal (2.2 and 0.6 cm) highly differentiated Papillary Renal Cell Carcinoma (Type 1) close to multiple papillary adenomas and chronic interstitial nephritis.

Classification pTNM 2010:

Stage: pT1a (m=3) LO VO Pn0

Grade: G1

R-Classification: R1

ICD-O: 8260/3.

Laterality = (L)

Source: NCI Genomic Data Commons file 4aa233ef-1ef3-41f4-8741-d04f75165005 (TCGA-5P-A9KF.096ABF46-EC92-4C6A-8D8F-05D48E8C2CA1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).